Surgical pathology report (de-identified scan), TCGA case TCGA-YZ-A983, project TCGA-UVM (Uveal Melanoma), tissue source site The Ohio State University, specimen TCGA-YZ-A983-01A (Primary Tumor).

[page 1 of 3]
Facility

Name

Result Information

Status

Final result

Provider Status

Reviewed

MD on

Observation Date and Time

Specimen Type

Tissue Procurement

Entry Date

Result Narrative

Surgical Pathology Report

Patient Name:

Accession #:

Med. Rec #:

Submitting Physician:

--- Clinical History ---

Neovascular glaucoma of right eye [365.63]. Intraocular tumor [239.89].

Total retinal detachment of right eye [361.05]. Medical history:

-year-old with large choroidal malignant tumor. Blind painful eye with
NVG. Gross photos. Evaluate malignant tumor. Differential diagnosis
includes metastasis and uveal melanoma.

---Final Pathologic Diagnosis---

- A. Right eye, resection:
- Choroidal melanoma (amelanotic), see synoptic report
- Iris neovascularization with partial angle closure
- Retinal detachment
- Cataract

SYNOPTIC REPORT FOR UVEAL MELANOMA

Procedure:

Enucleation:

Specimen Size:

For Enucleation:

Anteroposterior diameter: 25 mm

Horizontal diameter: 23 mm

Vertical diameter: 24 mm

Length of optic nerve: 11 mm

Diameter of optic nerve: 3 mm

Specimen Laterality:

Right

Tumor Site:

Other (specify): Posterior adjacent to optic disc

ICD O-3

Melanoma, epithelial cell

87713

Site, (R) Choroid

C69.3

9/3/12/14

[page 2 of 3]
Tumor Size: LBD: 16 mm (gross); 13 mm (from slide)
Height: 10 mm (gross); 11 mm (from slide)

Tumor Involvement of Ocular Structures:

Choroid posterior
Retina

Tumor Location After Sectioning (microscopic)

Distance from anterior edge of tumor to limbus at cut edge: 11 mm
Distance of posterior margin of tumor base from edge of optic disc: 0 mm
Growth Pattern: Solid

Histopathologic Type:

Epithelioid cell melanoma (greater than 90% epithelioid cells)

Histologic Grade (pG): pG3

Microscopic Tumor Extension

Tumor Location

Anterior margin between disc and equator

Posterior margin between disc and equator

Scleral Involvement:

None

Margins

No melanoma at margins

Extrasceral extension (for enucleation specimens) - negative

Pathologic Staging (pTNM) pT3a NX MX

Additional Pathologic Findings (select all that apply)

Mitotic rate (number of mitoses per 40X objective with a field area of 0.152 mm²): 1/40 high power fields

Microvascular patterns: poorly formed vascular mimicry patterns present

Vascular invasion (tumor vessels or other vessels): negative

Degree of pigmentation: none

Inflammatory cells/tumor infiltrating lymphocytes: present/mild

Drusen: none

Retinal detachment: present

Invasion of Bruch's membrane: yes

Nevus: negative

Hemorrhage: negative

Neovascularization: yes

Other: fibrous plaque overlying tumor

Comment(s): PAS stain was used to evaluate for possible vascular mimicry patterns. Cytokeratin AE1/3 is negative (ruling out carcinoma/metastasis); and HMB-45 and melanA are strongly positive, consistent with melanoma.

All controls show appropriate reactivity.

Immunohistochemical (IHC) testing for HER2 is performed according to manufacturer's instructions at

In-situ hybridization tests were developed by and are performed at the

All other IHC and histochemical tests were developed by and are performed at the

. All tests reported here, except those addressing HER2 overexpression as a predictive marker, are not required to have nor do they have FDA approval.

Electronically Signed By
M.D.

[page 3 of 3]
---SPECIMEN(S) RECEIVED:---

Neuropath, Eye, enucleation/evisceration

---GROSS DESCRIPTION:---

The specimen is received in one properly labeled container with the patient's name and accession number.

A. The specimen is designated "right eye" and consists of a 9.0 gram intact globe which is 25.0 mm from anterior to posterior, 23.0 mm horizontally, 24.0 mm vertically, with corneal measurements of 11 vertically and 12 horizontally. The optic nerve is 11.0 mm in length. Upon opening, the lens is intact and present. The tumor as measured by Dr. is 16.0 mm in width (largest basal diameter?) and 10.0 mm high.
TE3

Summary of Cassettes: A1-3, entire globe (trisected, middle slab with optic nerve and mass = A2)

Lab Use Only: Job ID [REDACTED]

Gross description by:

Patient Release Status:

This result is not viewable by the patient.

Patient Care Team

	Relationship	Specialty	Notifications	Start	End
MD [REDACTED]		Ophthalmology			
DO [REDACTED]		Medical Oncology	All results, Admissions		

Procedures with Linked Chargeables

Chargeable	CPT Code
	88305
	88305

Facility

Name

SURG PATH REQUEST (Order #

Criteria	fw 1/8/14	Yes	No

Source: NCI Genomic Data Commons file 1bde829b-1ecc-4dfc-b676-e934ba170640 (TCGA-YZ-A983.04B1F253-2351-4BA6-A289-A22BC1E19C35.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).